Somatic mutation profile of tumor specimen C3L-06070-54 (aliquot CPT0326140002) from CPTAC case C3L-06070, project CPTAC-3 (Hematopoietic and reticuloendothelial systems — Myeloid Leukemias). Sex at birth: female; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Hematopoietic system, NOS; Age at diagnosis: 50.7 years (18,514 days).
Specimen C3L-06070-54: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b449ab3e-5bfc-45cb-9058-a74513cb4f19.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-06070-51 (Buccal Cell Normal), aliquot CPT0326190002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/819732cb-874c-4d10-a668-bdeb5cc9c63b

The open-access MAF lists 9 somatic variants for this specimen: 5 protein-altering or splice-affecting, 3 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 3, Silent 3, Splice Region 1, Frame Shift Ins 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NPM1 | c.860_863dup p.W288Cfs*12 | Frame Shift Ins (INS) | VAF 12/62 reads (19%) | catalogued as rs587776806, COSV51548899, COSV51555098, COSV51559390, COSV51564309; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- CACNA2D2 | c.1626G>A p.T542= | Splice Region (SNP) | VAF 74/146 reads (51%) | catalogued as rs146279759; called by muse, mutect2, varscan2
- DNAH5 | c.10815T>A p.D3605E | Missense Mutation (SNP) | VAF 95/200 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CD065704; called by muse, mutect2, varscan2
- ANAPC2 | c.790A>G p.T264A | Missense Mutation (SNP) | VAF 86/211 reads (41%) | SIFT deleterious (0.04); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- CEP170B | c.2366C>G p.A789G (on ENST00000453495; = p.A718G on NM_015005.3) | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT tolerated (0.18); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- FAM120AOS | c.576A>G p.R192= | Silent (SNP) | VAF 15/47 reads (32%) | called by muse, mutect2, varscan2
- PES1 | c.924G>A p.A308= | Silent (SNP) | VAF 49/118 reads (42%) | catalogued as rs369510488; called by muse, mutect2, varscan2
- XKR6 | c.165C>T p.H55= | Silent (SNP) | VAF 34/324 reads (10%) | called by muse, varscan2
- PGLYRP1 | chr19:46019033 G>A | 3'Flank (SNP) | VAF 24/51 reads (47%) | called by muse, mutect2, varscan2
